Somatic mutation profile of tumor specimen MP2PRT-PAWCGS-TMP1-A (aliquot MP2PRT-PAWCGS-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAWCGS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.0 years (4,033 days).
Specimen MP2PRT-PAWCGS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10158894-806a-47a4-98a2-6bcf5b457ea8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCGS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCGS-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b56af071-9d8e-4e57-968a-863ea0eb099f

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 5, Silent 5, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGHV5-51 | c.82G>C p.A28P | Missense Mutation (SNP) | VAF 162/216 reads (75%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs183518874; called by muse, mutect2, varscan2
- LARP4B | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 273/494 reads (55%) | SIFT tolerated (0.41); PolyPhen probably damaging (1); catalogued as rs553851719, COSV60221606; called by muse, mutect2, varscan2
- LATS2 | c.1419_1420insACCCCC p.P473_A474insTP | In Frame Ins (INS) | VAF 20/326 reads (6%) | catalogued as rs981548933; called by mutect2, pindel
- SHOX2 | c.893C>G p.S298W (on ENST00000441443 / NM_006884.3; = p.S322W on NM_003030.4) | Missense Mutation (SNP) | VAF 269/609 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs759639920, COSV99072084; called by muse, mutect2, varscan2
- BAHCC1 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 176/369 reads (48%) | called by muse, varscan2
- CKAP4 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 202/485 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- POGLUT3 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRV1 | c.4107A>T p.G1369= | Silent (SNP) | VAF 158/356 reads (44%) | catalogued as rs1165727183, COSV101315349; called by muse, mutect2, varscan2
- DOK4 | c.840C>T p.I280= | Silent (SNP) | VAF 26/548 reads (5%) | catalogued as rs1359765983, COSV54672456; called by muse, mutect2
- EDC4 | c.2460G>A p.S820= | Silent (SNP) | VAF 26/506 reads (5%) | catalogued as rs750386083; called by muse, mutect2
- NLRP6 | c.2430G>A p.Q810= | Silent (SNP) | VAF 244/559 reads (44%) | called by muse, mutect2, varscan2
- ZDHHC2 | c.930G>A p.G310= | Silent (SNP) | VAF 132/293 reads (45%) | called by muse, mutect2, varscan2
